Somatic mutation profile of tumor specimen C3L-02969-02 (aliquot CPT0217420006) from CPTAC case C3L-02969, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA3; Tumor grade: G2; Age at diagnosis: 77.0 years (28,108 days).
Specimen C3L-02969-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff110727-60b0-4ac0-b80d-adce7ec09186.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02969-31 (Blood Derived Normal), aliquot CPT0219800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0fc1762-9ed9-4777-b97b-bdc81012330f

The open-access MAF lists 328 somatic variants for this specimen: 226 protein-altering or splice-affecting, 66 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 189, Silent 66, Intron 19, Nonsense Mutation 17, Frame Shift Del 10, RNA 7, Splice Site 6, 3'UTR 5, 5'Flank 4, Translation Start Site 2, Splice Region 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 22/276 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863224683, CM016206, COSV52686543, COSV52692226, COSV99368721; ClinVar: uncertain significance; called by muse, mutect2
- TP53 | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 39/271 reads (14%) | hotspot (GDC flag); catalogued as rs1064794618, COSV52751414, COSV53223969, COSV53499187; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.751T>A p.C251S | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1464716346; called by muse, mutect2, varscan2
- ACTR2 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 23/207 reads (11%) | catalogued as COSV53199099; called by muse, mutect2, varscan2
- ADCY5 | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1433750011; called by muse, mutect2
- ADGRB3 | c.1582C>G p.P528A | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.07); catalogued as COSV101000888; called by muse, mutect2
- ADM | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 69/433 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs771734789; called by muse, mutect2, varscan2
- AGK | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 19/125 reads (15%) | catalogued as rs1351271924; called by muse, mutect2, varscan2
- ATAD2 | c.3523G>A p.G1175S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.922); catalogued as rs1254688795; called by muse, varscan2
- BCORL1 | c.5093G>T p.R1698L | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs756266434; called by muse, mutect2, varscan2
- CACNG7 | c.641C>A p.P214Q | Missense Mutation (SNP) | VAF 63/298 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV55812931; called by muse, mutect2, varscan2
- CARS2 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774407462, COSV57285411; called by muse, mutect2, varscan2
- CEACAM18 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV101140398; called by muse, mutect2, varscan2
- CHERP | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs771837058; called by muse, mutect2, varscan2
- COL11A1 | c.2787C>A p.F929L | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV100614246; called by muse, mutect2
- COL13A1 | c.1930G>T p.E644* (on ENST00000398978 / NM_001130103.2; = p.E572* on NM_080798.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 85/346 reads (25%) | catalogued as COSV62573165; called by muse, mutect2, varscan2
- COL16A1 | c.3796C>T p.P1266S | Missense Mutation (SNP) | VAF 51/373 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs907747180; called by muse, mutect2, varscan2
- CR1 | c.3373T>A p.W1125R | Missense Mutation (SNP) | VAF 158/795 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756426946; called by muse, mutect2, varscan2
- DAXX | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs773398360, COSV56472310; called by muse, mutect2
- DNMT1 | c.4642G>A p.V1548M | Missense Mutation (SNP) | VAF 51/417 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1299212888; called by muse, mutect2, varscan2
- EGFR | c.2570G>A p.G857E | Missense Mutation (SNP) | VAF 107/674 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51793933, COSV51830659; called by muse, mutect2, varscan2
- ESR2 | c.727G>T p.G243C | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs1050115725; called by muse, mutect2
- F12 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 109/615 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.494); catalogued as COSV53693126; called by muse, mutect2, varscan2
- FRMD4A | c.2731C>T p.R911C | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1470548395; called by muse, mutect2
- GABRA4 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs763817157, COSV51922640, COSV51927656; called by muse, mutect2, varscan2
- GATA3 | c.950G>T p.C317F | Missense Mutation (SNP) | VAF 165/739 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1410932; called by muse, mutect2, varscan2
- GBP5 | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 14/188 reads (7%) | catalogued as COSV58594400; called by muse, mutect2
- GRXCR1 | c.631G>C p.A211P | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101295628; called by muse, mutect2
- HOXC11 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs903945259; called by muse, mutect2, varscan2
- HSD3B2 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 65/385 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs765748123, COSV65594095; called by muse, mutect2, varscan2
- HTR1B | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs201262698; called by muse, mutect2, varscan2
- IGHD | c.1145T>C p.L382P | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs1324942580; called by muse, mutect2, varscan2
- IGHV1-46 | c.329C>A p.T110K | Missense Mutation (SNP) | VAF 68/436 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs781917710; called by mutect2, varscan2
- KIF13B | c.3075+1G>T p.X1025_splice | Splice Site (SNP) | VAF 32/246 reads (13%) | catalogued as rs1415898095; called by muse, mutect2, varscan2
- LAMA3 | c.8458C>G p.L2820V (on ENST00000313654 / NM_198129.4; = p.L1211V on NM_000227.6) | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52532598; called by muse, mutect2, varscan2
- LILRA4 | c.646C>A p.L216M | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52492145; called by muse, mutect2
- LRP1 | c.10295G>T p.R3432L | Missense Mutation (SNP) | VAF 25/259 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99675534; called by muse, mutect2, varscan2
- LTBR | c.1294A>G p.I432V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs552582823; called by mutect2, varscan2
- MNX1 | c.1104C>A p.F368L | Missense Mutation (SNP) | VAF 44/609 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.899); catalogued as COSV53320037; called by muse, mutect2
- MS4A6A | c.145G>T p.G49W | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60622065; called by muse, mutect2
- NBAS | c.3938C>A p.P1313H | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs770372450; called by muse, mutect2, varscan2
- NEB | c.8722A>T p.I2908F | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756146889; called by muse, mutect2, varscan2
- NPTXR | c.535A>G p.M179V | Missense Mutation (SNP) | VAF 39/348 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs1259490935; called by muse, mutect2, varscan2
- NR2C2 | c.790G>C p.D264H (on ENST00000393102; = p.D283H on NM_003298.5) | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as COSV60147787; called by muse, mutect2, varscan2
- NRXN3 | c.1688G>T p.G563V (on ENST00000557594 / NM_001272020.2; = p.G987V on NM_004796.6) | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55322487; called by muse, mutect2
- NYAP2 | c.1703C>G p.A568G | Missense Mutation (SNP) | VAF 37/368 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.059); catalogued as COSV56007357; called by muse, mutect2
- OR10K2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59220725; called by muse, mutect2, varscan2
- OR13F1 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV58252722; called by muse, mutect2
- OR2T4 | c.18del p.W6* | Frame Shift Del (DEL) | VAF 24/212 reads (11%) | catalogued as COSV63543232; called by mutect2, pindel*
- OR9G4 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57247618; called by muse, mutect2
- OSBPL5 | c.613A>G p.K205E | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.077); catalogued as COSV104376173; called by muse, mutect2
- PARVB | c.652C>A p.H218N | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.028); catalogued as COSV58685050; called by muse, mutect2, varscan2
- PCDH15 | c.4880C>A p.T1627K | Missense Mutation (SNP) | VAF 90/526 reads (17%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as COSV100226497, COSV57376391; called by mutect2, varscan2
- PPM1L | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs369097835; called by muse, mutect2, varscan2
- PRAME | c.201G>C p.Q67H | Missense Mutation (SNP) | VAF 34/345 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs766008323; called by muse, mutect2
- PRB1 | c.788C>A p.P263H | Missense Mutation (SNP) | VAF 109/529 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as rs1303924609; called by muse, mutect2, varscan2
- RTL10 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs973323916; called by muse, mutect2
- SLITRK2 | c.2284C>T p.R762* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as rs1556945144, COSV59427015; called by muse, mutect2, varscan2
- SORCS1 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV53860632; called by muse, mutect2, varscan2
- SRD5A1 | c.596A>G p.Y199C | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763896001; called by muse, mutect2, varscan2
- SRD5A3 | c.346G>C p.G116R | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs529002297, COSV51712777; called by muse, mutect2, varscan2
- SULT1C2 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs770588662; called by muse, mutect2
- SYNE3 | c.747del p.N250Tfs*56 | Frame Shift Del (DEL) | VAF 28/274 reads (10%) | catalogued as COSV100516152; called by mutect2, varscan2
- TAS2R20 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.344); catalogued as COSV67852141; called by muse, mutect2
- TBC1D16 | c.1294G>T p.G432W | Missense Mutation (SNP) | VAF 65/339 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV60478440; called by muse, mutect2, varscan2
- TGIF2LX | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 26/367 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs780908528; called by muse, mutect2
- TMEM132D | c.2570C>A p.T857K | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67162794, COSV99066529; called by muse, mutect2
- TMEM63B | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 14/398 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1224787005; called by muse, mutect2
- TPO | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 134/677 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.026); catalogued as rs200427779; called by muse, mutect2, varscan2
- TPTE | c.163A>T p.I55F | Missense Mutation (SNP) | VAF 58/497 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs766581855; called by muse, mutect2, varscan2
- TTN | c.53224C>G p.L17742V (on ENST00000591111; = p.L10318V on NM_003319.4) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | PolyPhen benign (0.243); catalogued as rs1296087829; called by muse, mutect2
- USH2A | c.2833G>A p.A945T | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs1412167321; called by muse, mutect2
- VPS45 | c.734A>G p.N245S | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as rs1320022085; called by muse, mutect2
- ZNF100 | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs747526452; called by muse, mutect2, varscan2
- ZNF804B | c.2074G>A p.G692R | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV60854510; called by muse, mutect2
- ADAMTS12 | c.2528G>T p.G843V | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY3 | c.2327A>G p.K776R | Missense Mutation (SNP) | VAF 151/711 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKAP9 | c.10718G>A p.W3573* (on ENST00000359028; = p.W3549* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/153 reads (7%) | called by muse, mutect2
- AMPD2 | c.260G>C p.R87P | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ANKRD31 | c.4198G>T p.A1400S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- APBA1 | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- APOB | c.1999C>A p.L667I | Missense Mutation (SNP) | VAF 77/306 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ARPIN | c.36C>A p.N12K | Missense Mutation (SNP) | VAF 93/348 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASAH2 | c.290A>T p.Q97L | Missense Mutation (SNP) | VAF 25/323 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); called by muse, mutect2
- ASB16 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 171/734 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ASXL1 | c.2599G>A p.G867R | Missense Mutation (SNP) | VAF 114/500 reads (23%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- ATP10A | c.938G>T p.C313F | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- ATP10D | c.1285C>A p.L429M | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BARD1 | c.1586G>T p.R529L | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- BBS12 | c.997G>T p.G333* | Nonsense Mutation (SNP) | VAF 44/278 reads (16%) | called by muse, mutect2, varscan2
- BCL7A | c.476A>G p.E159G | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); called by muse, mutect2
- C1orf94 | c.709A>T p.S237C (on ENST00000488417 / NM_001134734.2; = p.S47C on NM_032884.5) | Missense Mutation (SNP) | VAF 42/270 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- C6orf118 | c.377C>A p.T126N | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CA9 | c.1151G>T p.R384L | Missense Mutation (SNP) | VAF 59/334 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CABP5 | c.94+7C>G | Splice Region (SNP) | VAF 33/213 reads (15%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.1533T>A p.Y511* | Nonsense Mutation (SNP) | VAF 21/236 reads (9%) | called by muse, mutect2
- CALB2 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CALCA | c.382A>G p.R128G | Missense Mutation (SNP) | VAF 53/465 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CCNT1 | c.1504A>G p.K502E | Missense Mutation (SNP) | VAF 44/419 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CCNT2 | c.2086G>T p.G696C (on ENST00000264157 / NM_058241.3; = p.R662L on NM_001241.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CD163L1 | c.3498C>A p.S1166R | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CD163L1 | c.3335T>A p.L1112* | Nonsense Mutation (SNP) | VAF 54/350 reads (15%) | called by muse, mutect2, varscan2
- CEP170 | c.2277G>T p.W759C | Missense Mutation (SNP) | VAF 53/516 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- CFAP221 | c.2200C>A p.P734T | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CFHR4 | c.58+1G>T p.X20_splice | Splice Site (SNP) | VAF 22/142 reads (15%) | called by muse, mutect2, varscan2
- CHIA | c.559G>T p.G187C (on ENST00000343320; = p.G79C on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CLEC4C | c.385T>A p.F129I | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CNGA1 | c.223A>T p.R75W | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CNN3 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 26/138 reads (19%) | called by muse, mutect2, varscan2
- CNNM2 | c.1457G>T p.G486V | Missense Mutation (SNP) | VAF 101/709 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- CNTN1 | c.2585A>C p.Q862P | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- COL9A3 | c.1529C>A p.T510K | Missense Mutation (SNP) | VAF 85/550 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- DBF4 | c.946A>G p.R316G | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- DBX1 | c.673-1G>T p.X225_splice | Splice Site (SNP) | VAF 63/599 reads (11%) | called by muse, mutect2, varscan2
- DEPTOR | c.1177C>G p.L393V | Missense Mutation (SNP) | VAF 21/284 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2
- DIO3 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.845); called by muse, mutect2
- DIP2C | c.1802T>C p.V601A | Missense Mutation (SNP) | VAF 34/372 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2
- DNAH5 | c.1063del p.C355Vfs*12 | Frame Shift Del (DEL) | VAF 29/305 reads (10%) | called by mutect2, pindel, varscan2
- DNAH8 | c.10988A>T p.K3663M | Missense Mutation (SNP) | VAF 76/384 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.7438G>T p.A2480S | Missense Mutation (SNP) | VAF 90/756 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- DZIP1 | c.2489G>A p.W830* (on ENST00000347108; = p.W811* on NM_014934.5) | Nonsense Mutation (SNP) | VAF 18/140 reads (13%) | called by muse, mutect2, varscan2
- E2F8 | c.2104G>T p.V702F | Missense Mutation (SNP) | VAF 50/372 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- EGR4 | c.331T>A p.S111T (on ENST00000545030; = p.S8T on NM_001965.4) | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- EPHA1 | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 56/335 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERC1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.448); called by muse, varscan2
- EYS | c.6239C>A p.S2080Y | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- FAM149B1 | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- FAM47B | c.250A>T p.R84* | Nonsense Mutation (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2, varscan2
- FDXR | c.1154del p.G385Afs*15 (on ENST00000293195 / NM_024417.5; = p.G391Afs*15 on NM_004110.6) | Frame Shift Del (DEL) | VAF 31/179 reads (17%) | called by mutect2, pindel, varscan2
- FGD2 | c.1078G>T p.A360S | Missense Mutation (SNP) | VAF 58/284 reads (20%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- FGD4 | c.1622A>C p.H541P | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- FNIP2 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXI3 | c.1185C>A p.S395R | Missense Mutation (SNP) | VAF 120/417 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- FRMPD2 | c.2704G>C p.D902H | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.2); called by mutect2, varscan2
- GAA | c.2344G>A p.A782T | Missense Mutation (SNP) | VAF 58/288 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GGT5 | c.893T>C p.V298A | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, varscan2
- GREB1L | c.3452C>T p.S1151F | Missense Mutation (SNP) | VAF 64/398 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HAL | c.1427A>T p.N476I | Missense Mutation (SNP) | VAF 81/713 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HCN1 | c.2177A>T p.Q726L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- HECTD4 | c.6239G>A p.S2080N | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2
- HOXC5 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 47/626 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HTR1F | c.395C>A p.A132D | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- IFT122 | c.2041A>G p.I681V (on ENST00000348417 / NM_052989.3; = p.I622V on NM_018262.4) | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.891); called by muse, mutect2
- IL15RA | c.674C>A p.A225E | Missense Mutation (SNP) | VAF 31/312 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- KCNQ3 | c.1993T>A p.S665T | Missense Mutation (SNP) | VAF 41/591 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.067); called by muse, mutect2
- KIAA1549L | c.803T>C p.V268A (on ENST00000321505; = p.V565A on NM_012194.3) | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF13B | c.3075G>T p.Q1025H | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRTAP27-1 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.019); called by muse, mutect2
- LILRA6 | c.96G>T p.W32C | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMTK2 | c.3856G>T p.E1286* | Nonsense Mutation (SNP) | VAF 52/301 reads (17%) | called by muse, mutect2, varscan2
- LPA | c.4477C>A p.P1493T | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- LRP8 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 38/345 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC45 | c.1246G>C p.D416H | Missense Mutation (SNP) | VAF 35/356 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- MALRD1 | c.2145del p.W715Cfs*48 | Frame Shift Del (DEL) | VAF 31/175 reads (18%) | called by mutect2, pindel, varscan2
- MAP2 | c.4del p.A2? | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, varscan2
- MARCHF7 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.703); called by muse, mutect2
- METRN | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MFSD5 | c.118C>G p.R40G | Missense Mutation (SNP) | VAF 51/420 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MICAL2 | c.5761C>A p.Q1921K | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- MKI67 | c.6446T>C p.V2149A | Missense Mutation (SNP) | VAF 30/397 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- MLXIPL | c.901+1G>T p.X301_splice | Splice Site (SNP) | VAF 69/546 reads (13%) | called by muse, mutect2, varscan2
- MLXIPL | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 70/560 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- MN1 | c.3175G>T p.V1059L | Missense Mutation (SNP) | VAF 23/241 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2
- MROH9 | c.1942C>A p.H648N | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- NCAN | c.904G>T p.D302Y | Missense Mutation (SNP) | VAF 24/724 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NELL2 | c.2011A>T p.M671L | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.16); called by muse, mutect2
- NLRP7 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 57/333 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRCAM | c.908A>T p.Y303F (on ENST00000379028 / NM_001371124.1; = p.Y297F on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR13C2 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2
- OR2S2 | c.530A>T p.H177L | Missense Mutation (SNP) | VAF 90/484 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- OR4X2 | c.756G>T p.R252S | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR51C1P | c.510C>A p.H170Q | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR8H2 | c.763C>G p.L255V | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDHA7 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 203/1095 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCF11 | c.2036A>C p.Q679P | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- PGBD2 | c.658A>G p.R220G | Missense Mutation (SNP) | VAF 80/309 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIEZO2 | c.1147G>T p.G383W | Missense Mutation (SNP) | VAF 36/411 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- PIK3CA | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); called by muse, mutect2
- PLK1 | c.1801A>C p.K601Q | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- PLOD3 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 35/884 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.062); called by muse, mutect2
- POPDC2 | c.703G>C p.A235P | Missense Mutation (SNP) | VAF 40/297 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- PRR35 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 73/680 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRUNE2 | c.6034A>G p.S2012G | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- RAB3GAP2 | c.2863G>T p.V955L | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2
- RYR2 | c.5664del p.K1890Rfs*7 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- SERGEF | c.623G>C p.G208A | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- SERPINA12 | c.165A>T p.L55F | Missense Mutation (SNP) | VAF 26/562 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SERPINA9 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 19/380 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SH3GL2 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SHROOM1 | c.86_87del p.A29Gfs*216 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by pindel, varscan2
- SLFN12L | c.981C>G p.N327K (on ENST00000260908 / NM_001363830.1; = p.N345K on NM_001195790.1) | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- SMAD5 | c.514A>G p.T172A | Missense Mutation (SNP) | VAF 55/295 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SOX14 | c.194G>C p.R65P | Missense Mutation (SNP) | VAF 16/494 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPHKAP | c.4939C>A p.Q1647K (on ENST00000392056 / NM_001142644.2; = p.Q1618K on NM_030623.3) | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- SPRYD7 | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SRGAP1 | c.618G>C p.E206D | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- STARD9 | c.6400G>C p.E2134Q | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- STRAP | c.191del p.G64Vfs*4 | Frame Shift Del (DEL) | VAF 25/237 reads (11%) | called by mutect2, pindel*, varscan2*
- SYNE1 | c.20527del p.L6843Wfs*13 (on ENST00000367255 / NM_182961.4; = p.L6772Wfs*13 on NM_033071.3) | Frame Shift Del (DEL) | VAF 53/326 reads (16%) | called by mutect2, pindel, varscan2
- TAAR8 | c.210T>G p.I70M | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- TFAP2B | c.244A>T p.S82C | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TFAP2B | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); called by mutect2, varscan2
- TFAP2D | c.747G>T p.L249F | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2
- TGFB2 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 62/283 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM102 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- TMEM132C | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- TMEM132C | c.779A>T p.E260V | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.281); called by muse, mutect2
- TNN | c.3385T>A p.Y1129N | Missense Mutation (SNP) | VAF 33/414 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TRANK1 | c.5719G>T p.E1907* | Nonsense Mutation (SNP) | VAF 24/178 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.68909T>A p.V22970E (on ENST00000591111; = p.V15546E on NM_003319.4) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | PolyPhen possibly damaging (0.871); called by muse, mutect2
- TYRO3 | c.1031A>C p.E344A | Missense Mutation (SNP) | VAF 39/405 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.197); called by muse, mutect2
- UBQLNL | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 40/269 reads (15%) | called by muse, mutect2, varscan2
- UROC1 | c.1276A>G p.T426A | Missense Mutation (SNP) | VAF 69/504 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- VPS13A | c.4256A>G p.D1419G | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- WASHC4 | c.1455A>G p.A485= | Splice Region (SNP) | VAF 13/200 reads (7%) | called by muse, mutect2
- WRN | c.3138G>C p.K1046N | Missense Mutation (SNP) | VAF 48/325 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZAN | c.3452-4_3465del p.X1151_splice | Splice Site (DEL) | VAF 24/213 reads (11%) | called by mutect2, pindel
- ZBTB11 | c.1372A>G p.N458D | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZFHX4 | c.285C>A p.Y95* | Nonsense Mutation (SNP) | VAF 70/306 reads (23%) | called by muse, mutect2, varscan2
- ZNF107 | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2
- ZNF169 | c.1187A>T p.H396L | Missense Mutation (SNP) | VAF 35/444 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2
- ZNF202 | c.548A>G p.D183G | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF480 | c.1193C>G p.P398R | Missense Mutation (SNP) | VAF 7/179 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF728 | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZNF783 | c.548-3_548del p.X183_splice | Splice Site (DEL) | VAF 58/479 reads (12%) | called by mutect2, pindel, varscan2
- ZSCAN5C | c.1082G>T p.C361F | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ABCA12 | c.6078C>A p.G2026= (on ENST00000272895 / NM_173076.3; = p.G1708= on NM_015657.3) | Silent (SNP) | VAF 36/205 reads (18%) | catalogued as COSV99792793; called by muse, mutect2, varscan2
- ACCSL | c.822C>A p.S274= | Silent (SNP) | VAF 12/299 reads (4%) | catalogued as COSV101122237; called by muse, mutect2
- ACTN4 | c.1863C>G p.S621= | Silent (SNP) | VAF 38/796 reads (5%) | called by muse, mutect2
- ARHGAP22 | c.2043T>C p.F681= | Silent (SNP) | VAF 91/416 reads (22%) | called by muse, mutect2, varscan2
- ARID1B | c.5919A>G p.P1973= | Silent (SNP) | VAF 84/421 reads (20%) | called by muse, mutect2, varscan2
- ATP10A | c.2118G>T p.A706= | Silent (SNP) | VAF 81/487 reads (17%) | called by muse, mutect2, varscan2
- BCORL1 | c.5094G>T p.R1698= | Silent (SNP) | VAF 33/111 reads (30%) | called by muse, mutect2, varscan2
- BRINP1 | c.2145C>A p.P715= | Silent (SNP) | VAF 29/241 reads (12%) | called by muse, mutect2, varscan2
- CA9 | c.1152A>T p.R384= | Silent (SNP) | VAF 60/339 reads (18%) | called by muse, mutect2, varscan2
- CACHD1 | c.372A>G p.A124= | Silent (SNP) | VAF 23/175 reads (13%) | called by muse, mutect2, varscan2
- CACNB4 | c.177G>T p.P59= | Silent (SNP) | VAF 51/574 reads (9%) | catalogued as rs552093496, COSV52397033; called by muse, mutect2
- CCR2 | c.697C>A p.R233= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as COSV52747915; called by muse, mutect2, varscan2
- CELSR3 | c.3915G>T p.T1305= | Silent (SNP) | VAF 80/418 reads (19%) | catalogued as COSV51154509; called by muse, mutect2, varscan2
- CEP55 | c.1374T>C p.H458= | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- CHST6 | c.123G>T p.V41= | Silent (SNP) | VAF 35/222 reads (16%) | called by muse, mutect2, varscan2
- CLEC2D | c.471C>T p.I157= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as COSV51993003; called by mutect2, varscan2
- COL22A1 | c.2622C>A p.G874= | Silent (SNP) | VAF 22/342 reads (6%) | catalogued as rs150534962; called by muse, mutect2
- DCHS1 | c.1050G>A p.V350= | Silent (SNP) | VAF 70/435 reads (16%) | called by muse, mutect2, varscan2
- DGAT1 | c.1272A>T p.R424= | Silent (SNP) | VAF 32/374 reads (9%) | catalogued as COSV60048980; called by muse, mutect2
- DNAH5 | c.3135T>A p.P1045= | Silent (SNP) | VAF 73/427 reads (17%) | called by muse, mutect2, varscan2
- DYNC1I1 | c.135C>A p.P45= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV61466993; called by muse, mutect2, varscan2
- ERICH3 | c.3384C>T p.N1128= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs769950814, COSV58613714; called by muse, mutect2, varscan2
- ESRP2 | c.633C>T p.L211= | Silent (SNP) | VAF 29/270 reads (11%) | called by muse, mutect2, varscan2
- EXOC1 | c.114A>G p.L38= | Silent (SNP) | VAF 16/78 reads (21%) | called by mutect2, varscan2
- EZHIP | c.1065C>T p.A355= | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as rs1331523373; called by muse, mutect2
- FLNA | c.408G>T p.L136= | Silent (SNP) | VAF 92/281 reads (33%) | called by muse, mutect2, varscan2
- FRY | c.6363C>T p.F2121= | Silent (SNP) | VAF 22/258 reads (9%) | catalogued as COSV66567623, COSV66574979; called by muse, mutect2
- GATAD2A | c.558C>T p.T186= | Silent (SNP) | VAF 27/206 reads (13%) | catalogued as rs142000821; called by muse, mutect2, varscan2
- GBP5 | c.1449G>C p.T483= | Silent (SNP) | VAF 14/187 reads (7%) | catalogued as rs775677633; called by muse, mutect2
- GLYATL1 | c.687A>T p.V229= (on ENST00000317391 / NM_001354699.1; = p.V260= on NM_080661.4) | Silent (SNP) | VAF 17/290 reads (6%) | called by muse, mutect2
- GRB14 | c.1546C>T p.L516= | Silent (SNP) | VAF 22/206 reads (11%) | called by muse, mutect2, varscan2
- GRID2IP | c.208C>A p.R70= | Silent (SNP) | VAF 76/356 reads (21%) | catalogued as rs544688737; called by muse, mutect2, varscan2
- MKRN3 | c.153G>T p.A51= | Silent (SNP) | VAF 51/306 reads (17%) | catalogued as COSV100090750, COSV58809735; called by muse, mutect2, varscan2
- NLRP14 | c.1875C>T p.C625= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as rs1222592340; called by muse, mutect2, varscan2
- NOS1 | c.4179C>T p.N1393= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as rs1418951582; called by muse, mutect2, varscan2
- NOTCH3 | c.6027G>A p.R2009= | Silent (SNP) | VAF 56/481 reads (12%) | catalogued as rs1195647077; called by muse, mutect2, varscan2
- OR13C2 | c.786C>T p.P262= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as rs757037796; called by muse, mutect2
- OR1N1 | c.15C>A p.S5= | Silent (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2
- OR6B1 | c.669C>T p.A223= | Silent (SNP) | VAF 13/174 reads (7%) | called by muse, mutect2
- PAK3 | c.882A>T p.S294= (on ENST00000262836 / NM_001324328.2; = p.S279= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV53277335; called by muse, mutect2, varscan2
- PARPBP | c.1536G>A p.Q512= | Silent (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- PCDHB6 | c.1812G>T p.L604= | Silent (SNP) | VAF 150/870 reads (17%) | called by muse, varscan2
- PCNX2 | c.2619C>T p.F873= | Silent (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- PDE3A | c.3330G>T p.S1110= | Silent (SNP) | VAF 29/276 reads (11%) | catalogued as rs747690834, COSV62974571; called by muse, mutect2, varscan2
- PDPR | c.1299G>T p.R433= | Silent (SNP) | VAF 48/610 reads (8%) | called by muse, mutect2
- PKHD1 | c.6117G>A p.L2039= | Silent (SNP) | VAF 28/278 reads (10%) | called by muse, mutect2
- R3HCC1L | c.2244T>C p.L748= (on ENST00000612478 / NM_001256619.2; = p.L734= on NM_014472.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 32/184 reads (17%) | called by muse, mutect2, varscan2
- RFPL2 | c.36A>G p.A12= | Silent (SNP) | VAF 21/223 reads (9%) | called by muse, mutect2, varscan2
- RIMS1 | c.1089G>A p.R363= | Silent (SNP) | VAF 49/451 reads (11%) | called by muse, mutect2, varscan2
- SCN9A | c.4725T>A p.T1575= (on ENST00000303354; = p.T1564= on NM_002977.3) | Silent (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- SCRIB | c.4377G>A p.R1459= | Silent (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- SCRT1 | c.78C>T p.R26= | Silent (SNP) | VAF 8/182 reads (4%) | catalogued as COSV59781011; called by muse, mutect2
- SLC4A10 | c.2988T>C p.L996= (on ENST00000446997 / NM_001354461.2; = p.L966= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 33/244 reads (14%) | called by muse, mutect2, varscan2
- SNX12 | c.24T>C p.D8= | Silent (SNP) | VAF 18/82 reads (22%) | called by mutect2, varscan2
- SRSF5 | c.270T>C p.S90= | Silent (SNP) | VAF 12/239 reads (5%) | called by muse, mutect2
- TACC2 | c.7710G>T p.P2570= (on ENST00000334433; = p.P648= on NM_006997.4) | Silent (SNP) | VAF 40/247 reads (16%) | called by muse, mutect2, varscan2
- TAF4B | c.294C>T p.A98= | Silent (SNP) | VAF 121/675 reads (18%) | catalogued as rs746921063; called by muse, mutect2, varscan2
- TEX19 | c.204G>A p.E68= | Silent (SNP) | VAF 30/363 reads (8%) | called by muse, mutect2
- TMEM120A | c.750G>A p.A250= | Silent (SNP) | VAF 15/496 reads (3%) | catalogued as rs781997749; called by muse, mutect2
- TMEM132C | c.2850G>A p.L950= | Silent (SNP) | VAF 18/352 reads (5%) | called by muse, mutect2
- TRANK1 | c.5718A>T p.A1906= | Silent (SNP) | VAF 24/181 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.61710T>C p.N20570= (on ENST00000591111; = p.N13146= on NM_003319.4) | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.47874G>A p.G15958= (on ENST00000591111; = p.G8534= on NM_003319.4) | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV59960107; called by muse, mutect2
- WIF1 | c.81G>A p.E27= | Silent (SNP) | VAF 8/121 reads (7%) | called by muse, mutect2
- ZFHX4 | c.1476C>T p.T492= | Silent (SNP) | VAF 30/155 reads (19%) | catalogued as rs771878230, COSV99261336; called by muse, mutect2, varscan2
- ZIC4 | c.771G>C p.V257= | Silent (SNP) | VAF 8/242 reads (3%) | catalogued as COSV67173686; called by muse, mutect2
- ACSF3 | c.*585del | 3'UTR (DEL) | VAF 58/354 reads (16%) | called by mutect2, pindel, varscan2
- ADCY4 | c.931-18C>A | Intron (SNP) | VAF 25/178 reads (14%) | called by muse, mutect2, varscan2
- AQP1 | c.*209G>T | 3'UTR (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100310850; called by mutect2, varscan2
- ATP8B3 | c.1552+56G>T | Intron (SNP) | VAF 16/252 reads (6%) | called by muse, mutect2
- BHLHE22 | chr8:64576494 G>T | 5'Flank (SNP) | VAF 30/137 reads (22%) | called by muse, mutect2, varscan2
- CCDC28A-AS1 | n.253G>A | RNA (SNP) | VAF 9/66 reads (14%) | called by mutect2, varscan2
- CCSER1 | c.2010+3219C>T | Intron (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- CDC14A | c.1755+29C>G | Intron (SNP) | VAF 20/174 reads (11%) | called by muse, mutect2, varscan2
- CERKL | chr2:181657016 G>T | 5'Flank (SNP) | VAF 38/204 reads (19%) | called by muse, mutect2, varscan2
- CHN1 | c.*263G>T | 3'UTR (SNP) | VAF 25/148 reads (17%) | catalogued as rs1341274068; called by muse, mutect2, varscan2
- DCDC2 | c.923-80G>C | Intron (SNP) | VAF 30/159 reads (19%) | catalogued as COSV101015532; called by muse, mutect2, varscan2
- DHX34 | c.2600-182T>C | Intron (SNP) | VAF 100/521 reads (19%) | called by muse, mutect2, varscan2
- FCRL5 | c.1681+266G>A | Intron (SNP) | VAF 11/128 reads (9%) | called by muse, mutect2
- GABBR1 | c.-1+135G>T | Intron (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- GGA1 | c.204+65G>A | Intron (SNP) | VAF 13/334 reads (4%) | called by muse, mutect2
- GVINP1 | n.7060G>A | RNA (SNP) | VAF 25/160 reads (16%) | called by muse, mutect2, varscan2
- LINC01949 | n.1234G>T | RNA (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- LINC02118 | n.77C>G | RNA (SNP) | VAF 14/68 reads (21%) | called by muse, varscan2
- LINC02692 | n.729G>T | RNA (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- NDUFV2 | c.54+27G>A | Intron (SNP) | VAF 11/289 reads (4%) | called by muse, mutect2
- NR4A1 | c.160+3570G>C | Intron (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- PIP5K1A | c.1363+12C>A | Intron (SNP) | VAF 36/288 reads (13%) | catalogued as COSV62958285; called by muse, mutect2, varscan2
- PKHD1L1 | c.9327+520C>A | Intron (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- PSMB8 | c.*4dup | 3'UTR (INS) | VAF 64/336 reads (19%) | called by mutect2, pindel, varscan2
- RUNX1T1 | c.88+13264G>T | Intron (SNP) | VAF 19/100 reads (19%) | catalogued as COSV56155707; called by muse, mutect2, varscan2
- SH2D6 | n.156G>A | RNA (SNP) | VAF 33/178 reads (19%) | catalogued as rs753512606, COSV100442453; called by muse, mutect2, varscan2
- SMIM30 | c.-124+61G>C | Intron (SNP) | VAF 12/244 reads (5%) | called by muse, mutect2
- SUMF2 | c.396+30G>C | Intron (SNP) | VAF 44/486 reads (9%) | called by muse, mutect2
- TAF8 | chr6:42050515 C>A | 5'Flank (SNP) | VAF 35/274 reads (13%) | called by muse, mutect2, varscan2
- TMEM209 | c.-7A>T | 5'UTR (SNP) | VAF 57/435 reads (13%) | catalogued as rs372766670; called by muse, mutect2, varscan2
- TPH2 | c.609-10883G>T | Intron (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- TXLNB | c.1077+111del | Intron (DEL) | VAF 28/161 reads (17%) | catalogued as rs770712859; called by mutect2, pindel, varscan2
- UBBP4 | n.535A>T | RNA (SNP) | VAF 79/722 reads (11%) | catalogued as rs527469759; called by muse, mutect2, varscan2
- XKR4 | c.806+36810C>G | Intron (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- ZNF529 | chr19:36577267 C>A | 5'Flank (SNP) | VAF 33/160 reads (21%) | catalogued as rs1433464949; called by muse, varscan2
- ZNF99 | c.*594T>G | 3'UTR (SNP) | VAF 30/318 reads (9%) | catalogued as COSV101233732, COSV101233966; called by muse, mutect2
